Somatic mutation profile of tumor specimen TCGA-A2-A4S2-01A (aliquot TCGA-A2-A4S2-01A-12D-A25Q-09) from TCGA case TCGA-A2-A4S2, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating lobular mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.8 years (22,936 days).
Specimen TCGA-A2-A4S2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b6d710d-9b98-44b4-9d70-8e9e9def29c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A4S2-10A (Blood Derived Normal), aliquot TCGA-A2-A4S2-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/263ffdbe-07db-433f-be46-8dc5b42b5769

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, Nonsense Mutation 5, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHNAK | c.7289A>C p.E2430A | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV57219760; called by muse, mutect2, varscan2
- BCL9L | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs200863037, COSV58315167; called by muse, mutect2, varscan2
- CD163L1 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs753102710, COSV58019445; called by muse, mutect2, varscan2
- CDH1 | c.2505T>A p.Y835* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV55735997; called by muse, mutect2, varscan2
- CHD4 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV58904907; called by muse, mutect2, varscan2
- CLK2 | c.1289A>G p.Y430C (on ENST00000368361 / NM_001294339.2; = p.Y429C on NM_003993.4) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs959560795, COSV56946273; called by muse, mutect2, varscan2
- CPAMD8 | c.2543C>A p.T848N (on ENST00000651564; = p.T801N on NM_015692.5) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71596830; called by muse, mutect2, varscan2
- ENPP4 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV58089454; called by muse, mutect2, varscan2
- FAM47A | c.1217C>A p.T406N | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs772251379, COSV60498111; called by muse, mutect2, varscan2
- FLAD1 | c.83G>C p.R28T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | PolyPhen benign (0); catalogued as COSV52698037; called by muse, mutect2, varscan2
- FLG | c.4214C>A p.S1405* | Nonsense Mutation (SNP) | VAF 53/360 reads (15%) | catalogued as CM156630, COSV64244138; called by muse, mutect2, varscan2
- GLUL | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV59382680; called by muse, mutect2, varscan2
- GRXCR1 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as rs773562995, CM165102, COSV67672429; called by muse, mutect2, varscan2
- GSDMB | c.725T>C p.L242S (on ENST00000418519 / NM_001165958.1; = p.L229S on NM_001042471.1) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.29); catalogued as COSV58781504; called by muse, mutect2, varscan2
- IPO8 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV99805155; called by muse, mutect2, varscan2
- ITGB5 | c.1121C>A p.A374E | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56149704; called by muse, mutect2
- PALB2 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55167044, COSV99847927; called by muse, mutect2, varscan2
- PCDHB2 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1320022364, COSV52031612; called by muse, mutect2, varscan2
- PSMB5 | c.542C>A p.S181* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV57801496; called by muse, mutect2
- RPL36A | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV65717975; called by mutect2, varscan2
- SPTBN2 | c.3797C>A p.A1266E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.506); catalogued as COSV59455842; called by muse, mutect2, varscan2
- TNK2 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100361214; called by muse, mutect2
- TNKS | c.3854A>G p.N1285S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs767692118, COSV60051672; called by muse, mutect2, varscan2
- USP29 | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV54144277; called by muse, mutect2, varscan2
- FOXA1 | c.761_767delinsG p.F254_N256delinsC | In Frame Del (DEL) | VAF 24/90 reads (27%) | called by pindel, varscan2*
- NEU1 | c.889_898del p.D297Ifs*3 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- TBX3 | c.547_548dup p.M184Gfs*25 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- CCN5 | c.369C>T p.C123= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as COSV51937999; called by muse, mutect2, varscan2
- LRRC17 | c.54G>A p.L18= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs778069913, COSV50865798; called by muse, mutect2, varscan2
- MARCO | c.720A>G p.K240= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV59055930; called by muse, mutect2, varscan2
- PRKX | c.330C>T p.I110= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV53322118; called by muse, mutect2, varscan2
- SYMPK | c.1644C>T p.D548= | Silent (SNP) | VAF 39/180 reads (22%) | catalogued as rs773340509, COSV55613386; called by muse, mutect2, varscan2
- SYNC | c.1146C>T p.A382= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV65130714; called by muse, mutect2, varscan2
- TBC1D22B | c.720G>T p.R240= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV65143064; called by muse, mutect2
